Somatic mutation profile of tumor specimen TCGA-EF-5831-01A (aliquot TCGA-EF-5831-01A-01D-1811-10) from TCGA case TCGA-EF-5831, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 72.1 years (26,331 days).
Specimen TCGA-EF-5831-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa993719-b4fd-49b4-9fb0-6c90d390efb0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EF-5831-10A (Blood Derived Normal), aliquot TCGA-EF-5831-10A-01D-1657-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb1f8b22-ea4f-4110-b919-7f02bb257d09

The open-access MAF lists 166 somatic variants for this specimen: 133 protein-altering or splice-affecting, 31 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 125, Silent 31, Nonsense Mutation 6, RNA 2, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPM | c.4732C>T p.R1578* | Nonsense Mutation (SNP) | VAF 22/93 reads (24%) | catalogued as rs753406334, COSV54125634; ClinVar: pathogenic; called by muse, mutect2
- KRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 61/177 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs121913535, COSV55497378, COSV55502117, COSV55509530; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 44/64 reads (69%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- ABCC9 | c.4408C>G p.L1470V | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.633); catalogued as COSV53963987; called by muse, mutect2
- ACSM1 | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs549226687, COSV54635480; called by muse, mutect2
- ACTRT1 | c.320T>G p.L107R | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64418999, COSV64419064; called by muse, mutect2
- ANO4 | c.38C>T p.T13I | Missense Mutation (SNP) | VAF 85/189 reads (45%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.015); catalogued as rs144771429; called by muse, mutect2
- ARHGAP17 | c.220C>G p.L74V | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as rs763284866; called by muse, mutect2
- ARSI | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1484833838, COSV60817684; called by muse, mutect2
- ATP2B3 | c.2720C>T p.S907L | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.043); catalogued as rs1301057285, COSV54856832; called by muse, mutect2
- C7orf33 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as rs1224082344; called by muse, mutect2
- CACNA1G | c.3752G>A p.R1251Q | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs1488635776; called by muse, mutect2
- CERS1 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as rs374895377; ClinVar: uncertain significance; called by muse, mutect2
- CIPC | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 64/84 reads (76%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as rs750253707; called by muse, mutect2
- CRACR2A | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs201306081; called by muse, mutect2
- CYP4Z1 | c.304C>A p.L102I | Missense Mutation (SNP) | VAF 77/136 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.388); catalogued as rs577489518, COSV61964725, COSV61965251; called by muse, mutect2
- DNAH10 | c.4759G>A p.V1587M (on ENST00000409039; = p.V1526M on NM_207437.3) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.14); catalogued as rs369698018; called by muse, mutect2
- DSE | c.2729C>G p.A910G | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.081); catalogued as rs377694163; called by muse, mutect2
- EXPH5 | c.1106C>T p.S369L | Missense Mutation (SNP) | VAF 46/212 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56201780; called by muse, mutect2
- FRY | c.3868G>A p.V1290I | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT tolerated (0.9); PolyPhen benign (0.281); catalogued as rs1433251989; called by muse, mutect2
- FSHR | c.897A>C p.Q299H | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV100437660, COSV58623202; called by muse, mutect2
- GCM1 | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs374038938; called by muse, mutect2
- GPRIN3 | c.696G>T p.M232I | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as COSV60886602; called by muse, mutect2
- HTR3A | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs918546404, COSV55471345, COSV55471669; called by muse, mutect2
- IGLV1-50 | c.71C>T p.T24M | Missense Mutation (SNP) | VAF 56/90 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as rs368561682; called by muse, mutect2
- INHA | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs370513243, CM143256, COSV54716147; called by muse, mutect2
- KIF21B | c.4391C>T p.T1464M (on ENST00000422435 / NM_001252100.2; = p.T1451M on NM_017596.4) | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.488); catalogued as rs146916477; called by muse, mutect2
- KIRREL2 | c.2107C>T p.R703C (on ENST00000360202 / NM_199180.4; = p.A613V on NM_032123.7) | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs374425895; called by muse, mutect2
- MGAT4C | c.1268G>T p.R423M | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1160157713; called by muse, mutect2
- NCDN | c.744G>T p.L248F | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV104395302; called by muse, mutect2
- NOX3 | c.995C>T p.S332L | Missense Mutation (SNP) | VAF 54/92 reads (59%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs376763861; called by muse, mutect2
- NR0B1 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.521); catalogued as rs1408937544, COSV66764687; called by muse, mutect2
- NWD1 | c.1787C>T p.A596V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as rs201427361; called by muse, mutect2
- OPN5 | c.947G>T p.C316F | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.143); catalogued as COSV99789880; called by muse, mutect2
- PCDH17 | c.2489C>T p.A830V | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs868610348; called by muse, mutect2
- PDE4DIP | c.6770C>T p.A2257V | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.891); catalogued as rs782199862, COSV57680855, COSV57699473; called by muse, mutect2
- PLPPR5 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 30/70 reads (43%) | catalogued as rs1393776818, COSV54178773; called by muse, mutect2
- PLXNA3 | c.1876G>A p.V626M | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.072); catalogued as rs375186286, COSV63753811, COSV63755743; called by muse, mutect2
- PTPRZ1 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 50/234 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.925); catalogued as rs1385479485, COSV66443655; called by muse, mutect2
- RAPGEF6 | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57249754; called by muse, mutect2
- REG1A | c.302G>A p.G101D | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52070422; called by muse, mutect2
- RPS6KA1 | c.1988G>A p.R663H | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs778048097; called by muse, mutect2
- SETMAR | c.1343A>T p.K448M | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.947); catalogued as rs1193862305; called by muse, mutect2
- SLC5A8 | c.1285G>A p.A429T | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs150897103, COSV73311178; called by muse, mutect2
- SLC8A3 | c.2770A>G p.I924V (on ENST00000381269 / NM_183002.3; = p.I922V on NM_033262.4) | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.801); catalogued as rs1157555556; called by muse, mutect2
- SNAPC4 | c.2401G>A p.D801N | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs139682930; called by muse, mutect2
- SNX25 | c.1258G>A p.G420S | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as rs1419410933; called by muse, mutect2
- SORBS2 | c.1279G>A p.V427I | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs183254057; called by muse, mutect2
- SORCS1 | c.2283G>C p.Q761H | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as COSV53898419, COSV99542179; called by muse, mutect2
- SPATA31A1 | c.2071C>T p.R691W | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.409); catalogued as rs1364577801; called by muse, mutect2
- TAF1L | c.3754C>T p.R1252W | Missense Mutation (SNP) | VAF 17/330 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54259076; called by muse, mutect2
- TEX2 | c.2036G>T p.R679I | Missense Mutation (SNP) | VAF 47/203 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as COSV51977632; called by muse, mutect2
- THSD7A | c.1617A>T p.K539N | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs772216671; called by muse, mutect2
- TRMT2A | c.313C>G p.L105V | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.574); catalogued as COSV52815329; called by muse, mutect2
- TTN | c.3040A>C p.T1014P (on ENST00000591111; = p.T968P on NM_003319.4) | Missense Mutation (SNP) | VAF 11/170 reads (6%) | PolyPhen probably damaging (0.976); catalogued as COSV60241284; called by muse, mutect2
- UBR3 | c.5647C>A p.P1883T | Missense Mutation (SNP) | VAF 54/316 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV55849715; called by muse, mutect2
- VPS13C | c.7706G>A p.R2569H (on ENST00000644861 / NM_020821.3; = p.R2526H on NM_017684.5) | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.223); catalogued as rs771908102; called by muse, mutect2
- ZNF354A | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 68/244 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs913690436; called by muse, mutect2
- ABCB1 | c.256G>C p.E86Q | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2
- ABCC2 | c.2704A>C p.T902P | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- ABI3BP | c.26T>A p.L9H | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADAM9 | c.1793C>G p.T598S | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.173); called by muse, mutect2
- ADAMTS9 | c.4709C>T p.T1570I | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- AKAP6 | c.4348A>G p.T1450A | Missense Mutation (SNP) | VAF 96/126 reads (76%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.057); called by muse, mutect2
- ARHGEF19 | c.2071G>C p.E691Q | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); called by muse, mutect2
- CAPSL | c.166A>G p.N56D | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2
- CDH12 | c.598T>A p.Y200N | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CENPBD1 | c.524T>A p.I175N | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.034); called by muse, mutect2
- CIITA | c.1240C>T p.R414* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2
- CNGA2 | c.1294C>A p.L432M | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CSMD2 | c.8867G>A p.G2956E | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- CSPP1 | c.3596T>C p.V1199A (on ENST00000676605; = p.V1158A on NM_024790.6) | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT tolerated (0.69); PolyPhen benign (0.01); called by muse, mutect2
- DLGAP3 | c.1513C>T p.R505W | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.425); called by muse, mutect2
- DNAAF4 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 60/121 reads (50%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2
- DNAH7 | c.81G>A p.E27= | Splice Region (SNP) | VAF 12/188 reads (6%) | called by muse, mutect2
- DOCK10 | c.3936G>T p.K1312N | Missense Mutation (SNP) | VAF 64/386 reads (17%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); called by muse, mutect2
- DOCK10 | c.2207A>T p.H736L | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ERCC6L | c.1537C>G p.L513V | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); called by muse, mutect2
- FAM193A | c.41A>G p.K14R | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2
- FAT4 | c.6613G>A p.D2205N | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.992); called by muse, mutect2
- FCRL1 | c.488C>A p.S163* | Nonsense Mutation (SNP) | VAF 12/234 reads (5%) | called by muse, mutect2
- FOXL1 | c.67C>A p.P23T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.059); called by muse, mutect2
- GLDC | c.3025G>T p.E1009* | Nonsense Mutation (SNP) | VAF 46/126 reads (37%) | called by muse, mutect2
- GLO1 | c.180A>C p.K60N | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- GYS2 | c.1273C>G p.L425V | Missense Mutation (SNP) | VAF 56/180 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.005); called by muse, mutect2
- HAVCR1 | c.960C>G p.F320L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2
- HK2 | c.2070G>A p.M690I | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.15); called by muse, mutect2
- KCTD10 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIAA0319 | c.1750T>C p.Y584H | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.929); called by muse, mutect2
- KIF18B | c.1071C>A p.S357R | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by muse, mutect2
- KLHL24 | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LBHD1 | c.568A>G p.S190G (on ENST00000431002 / NM_001367940.1; = p.S164G on NM_024099.3) | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.356); called by muse, mutect2
- LVRN | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.092); called by muse, mutect2
- MAGEL2 | c.2806C>A p.H936N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.001); called by muse, mutect2
- MBD5 | c.1250T>G p.M417R | Missense Mutation (SNP) | VAF 61/202 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2
- MLLT10 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2
- MPEG1 | c.1720G>C p.V574L | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.113); called by muse, mutect2
- NEB | c.17103C>G p.N5701K | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.547); called by muse, mutect2
- NEXN | c.1675G>T p.E559* | Nonsense Mutation (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2
- NFIB | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 17/270 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- NUP155 | c.3582C>G p.D1194E (on ENST00000231498 / NM_153485.3; = p.D1135E on NM_004298.4) | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.177); called by muse, mutect2
- OR51I1 | c.575G>T p.G192V | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2
- OR6C2 | c.137T>G p.L46R | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- OR6M1 | c.867G>C p.L289F | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.102); called by muse, mutect2
- OSBPL1A | c.41G>T p.R14I | Missense Mutation (SNP) | VAF 28/798 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PAPPA | c.4235C>T p.P1412L | Missense Mutation (SNP) | VAF 11/188 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2
- PHF20L1 | c.2273A>T p.E758V | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PLCL2 | c.1706C>T p.A569V (on ENST00000615277 / NM_001144382.2; = p.A443V on NM_015184.5) | Missense Mutation (SNP) | VAF 7/197 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); called by muse, mutect2
- POGLUT2 | c.280G>C p.D94H | Missense Mutation (SNP) | VAF 68/144 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- POLR2H | c.233C>T p.T78I | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- PROM2 | c.2391C>G p.I797M | Missense Mutation (SNP) | VAF 36/183 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2
- PTPRN | c.1537G>T p.A513S | Missense Mutation (SNP) | VAF 93/125 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2
- RAB3C | c.637A>G p.R213G | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- RESF1 | c.1691T>A p.V564D | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); called by muse, mutect2
- SLC37A2 | c.694+2T>C p.X232_splice | Splice Site (SNP) | VAF 20/108 reads (19%) | called by muse, mutect2
- SLC37A2 | c.1455C>G p.I485M | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.063); called by muse, mutect2
- SLC5A3 | c.1231G>T p.G411W | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPTB | c.4789G>A p.E1597K | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); called by muse, mutect2
- STRADB | c.166T>A p.S56T | Missense Mutation (SNP) | VAF 58/316 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2
- TBL2 | c.515G>T p.G172V | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TCAF2 | c.1055C>G p.A352G | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- TCERG1L | c.938A>C p.E313A | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.039); called by muse, mutect2
- TDO2 | c.763G>C p.A255P | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.625); called by muse, mutect2
- TEX15 | c.5200C>A p.P1734T (on ENST00000256246; = p.P2117T on NM_001350162.2) | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2
- UBE2A | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 60/84 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2
- UNC80 | c.121C>A p.Q41K | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2
- VCAN | c.9437T>G p.F3146C | Missense Mutation (SNP) | VAF 11/317 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- VEGFC | c.286C>A p.Q96K | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2
- VPS51 | c.2236G>A p.E746K | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- ZDHHC13 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); called by muse, mutect2
- ZNF282 | c.1684A>T p.I562F | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2
- ZNF544 | c.1715G>C p.G572A | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2
- ZNF585A | c.2211G>T p.Q737H (on ENST00000292841 / NM_001288800.2; = p.Q682H on NM_152655.3) | Missense Mutation (SNP) | VAF 11/203 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2
- ADAMTS15 | c.1710C>T p.C570= | Silent (SNP) | VAF 22/62 reads (35%) | called by muse, mutect2
- AKAP12 | c.540C>G p.G180= | Silent (SNP) | VAF 9/92 reads (10%) | called by muse, mutect2
- AP2A1 | c.1659C>A p.P553= | Silent (SNP) | VAF 83/151 reads (55%) | catalogued as rs201965025; called by muse, mutect2
- APCS | c.132G>A p.P44= | Silent (SNP) | VAF 26/100 reads (26%) | catalogued as rs371650621; called by muse, mutect2
- ASTN1 | c.1065C>T p.N355= | Silent (SNP) | VAF 48/160 reads (30%) | catalogued as rs61758728; called by muse, mutect2
- ATXN7L2 | c.2118G>A p.P706= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs754742143; called by muse, mutect2
- CCDC178 | c.381T>G p.T127= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV100284911; called by muse, mutect2
- CD244 | c.438G>A p.L146= (on ENST00000368033 / NM_001166663.2; = p.L141= on NM_016382.4) | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as rs1346174322; called by muse, mutect2
- CYBA | c.333C>T p.T111= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs978238415; ClinVar: likely benign; called by muse, mutect2
- FNDC11 | c.777C>T p.G259= | Silent (SNP) | VAF 28/99 reads (28%) | catalogued as rs1241489880; called by muse, mutect2
- GCLC | c.579A>G p.R193= (on ENST00000643939; = p.R191= on NM_001498.4) | Silent (SNP) | VAF 78/282 reads (28%) | called by muse, mutect2
- GPN2 | c.390A>G p.Q130= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as rs746292390, COSV64651847; called by muse, mutect2
- GRIK2 | c.2295C>T p.G765= | Silent (SNP) | VAF 37/184 reads (20%) | catalogued as rs372392956; called by muse, mutect2
- HSPH1 | c.502T>C p.L168= | Silent (SNP) | VAF 16/174 reads (9%) | called by muse, mutect2
- KLHL32 | c.258C>T p.H86= | Silent (SNP) | VAF 29/108 reads (27%) | catalogued as rs531719235, COSV65114989; called by muse, mutect2
- MAGEA3 | c.516C>A p.I172= | Silent (SNP) | VAF 88/202 reads (44%) | catalogued as COSV64756383, COSV64756706; called by muse, mutect2
- NOC2L | c.279C>T p.S93= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as rs776365603; called by muse, mutect2
- OR2G6 | c.639C>A p.L213= | Silent (SNP) | VAF 30/382 reads (8%) | called by muse, mutect2
- PCDHB2 | c.870T>C p.I290= | Silent (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2
- PCDHGC3 | c.2415C>T p.S805= | Silent (SNP) | VAF 10/135 reads (7%) | catalogued as rs771145308; called by muse, mutect2
- PKD2 | c.2700C>T p.I900= | Silent (SNP) | VAF 18/67 reads (27%) | called by muse, mutect2
- PTCHD3 | c.726G>A p.A242= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs768736791, COSV71256499; called by muse, mutect2
- SIX4 | c.942T>C p.S314= | Silent (SNP) | VAF 14/174 reads (8%) | called by muse, mutect2
- SPAG5 | c.150C>T p.T50= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs147639770, COSV58804509; called by muse, mutect2
- STK11 | c.495G>A p.E165= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as rs370446299; ClinVar: likely benign; called by muse, mutect2
- SUPT20HL1 | c.951C>A p.S317= | Silent (SNP) | VAF 95/278 reads (34%) | called by muse, mutect2
- SYNE1 | c.3480C>T p.H1160= (on ENST00000367255 / NM_182961.4; = p.H1167= on NM_033071.3) | Silent (SNP) | VAF 69/117 reads (59%) | catalogued as rs757238055; ClinVar: uncertain significance; called by muse, mutect2
- TTN | c.8331T>C p.Y2777= (on ENST00000591111; = p.Y2731= on NM_003319.4) | Silent (SNP) | VAF 30/173 reads (17%) | called by muse, mutect2
- VCAN | c.2700T>C p.S900= | Silent (SNP) | VAF 24/128 reads (19%) | called by muse, mutect2
- ZNF23 | c.1110A>T p.G370= | Silent (SNP) | VAF 16/76 reads (21%) | called by muse, mutect2
- ZYG11B | c.2103C>A p.I701= | Silent (SNP) | VAF 18/130 reads (14%) | catalogued as COSV53755842; called by muse, mutect2
- LINC00173 | n.913C>T | RNA (SNP) | VAF 16/113 reads (14%) | called by muse, mutect2
- NXF5 | n.656A>C | RNA (SNP) | VAF 40/590 reads (7%) | called by muse, mutect2
